Somatic mutation profile of tumor specimen 0DVSC5 from CCDI case PBCNCM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.5 years (2,025 days).
Specimen 0DVSC5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0dc5ac7-cb73-47f5-84fb-07d2246c9d71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSCB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0db90ab4-dbf9-4d81-8409-6a7d33b81182

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAVS | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 73/527 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); catalogued as rs143802036; called by muse, mutect2, varscan2
- DCAF12L2 | c.171_202del p.R58Pfs*50 | Frame Shift Del (DEL) | VAF 82/280 reads (29%) | called by mutect2, varscan2
- PXT1 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 32/808 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- USP24 | c.2262A>C p.E754D | Missense Mutation (SNP) | VAF 56/1361 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CYP26A1 | c.1380C>T p.A460= | Silent (SNP) | VAF 22/734 reads (3%) | called by muse, mutect2
- CYTH4 | c.20-12G>T | Intron (SNP) | VAF 32/275 reads (12%) | called by muse, mutect2, varscan2
- SULT1C2 | c.375+52C>T | Intron (SNP) | VAF 81/562 reads (14%) | catalogued as rs779252007; called by muse, mutect2, varscan2
